TARGET case TARGET-00-SJNORM016096 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/0f0a34ef-7597-40ee-ad1c-878ae8de5d5a

Biospecimens (4 samples)
- Samples TARGET-00-SJNORM016096-14A.1, TARGET-00-SJNORM016096-14A.2, TARGET-00-SJNORM016096-14A.3, TARGET-00-SJNORM016096-14A.4 (4 with the same recorded description): Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
